Somatic mutation profile of tumor specimen TCGA-MQ-A4LC-01A (aliquot TCGA-MQ-A4LC-01A-31D-A34C-32) from TCGA case TCGA-MQ-A4LC, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 54.4 years (19,866 days).
Specimen TCGA-MQ-A4LC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78c4a9a1-ad23-4fa3-8975-9199003fb583.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A4LC-10B (Blood Derived Normal), aliquot TCGA-MQ-A4LC-10B-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb4879ba-9b49-4678-9428-fa90da39b582

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGL2 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV104373492; called by muse, mutect2, varscan2
- GCM1 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs374038938; called by muse, mutect2, varscan2
- PLCXD2 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67340676; called by muse, mutect2, varscan2
- RASAL1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1049091761, COSV55658604; called by muse, mutect2, varscan2
- SEPTIN2 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs759279492; called by muse, mutect2, varscan2
- SP100 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV51002890; called by muse, mutect2, varscan2
- ADGRA3 | c.3580G>A p.V1194I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ATRN | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- CCDC78 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- EPHB4 | c.521T>G p.F174C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM102A | c.166T>G p.C56G | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- GCNT4 | c.681T>A p.C227* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- GK2 | c.1077C>A p.Y359* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- KAT2B | c.384_386del p.I129del | In Frame Del (DEL) | VAF 18/76 reads (24%) | called by pindel, varscan2
- LGALSL | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.165); called by mutect2, varscan2
- NDST2 | c.433A>C p.K145Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PIPOX | c.582A>C p.Q194H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POLE | c.3194G>T p.G1065V | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A3 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SNX19 | c.1194T>G p.I398M | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.31); called by muse, mutect2
- TMED2 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ABCC10 | c.3924C>T p.G1308= (on ENST00000372530 / NM_001198934.2; = p.G1280= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs776830198; called by muse, mutect2, varscan2
- GPR179 | c.6060T>C p.C2020= (on ENST00000621958; = p.C2019= on NM_001004334.4) | Silent (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- MGME1 | c.24C>T p.T8= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- TENM3 | c.576C>T p.H192= | Silent (SNP) | VAF 49/147 reads (33%) | called by muse, mutect2, varscan2
